CCDI case PBCINL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/64300d5d-369e-4164-b39e-44bf1025fbb6

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 7.0 years (2,575 days).

Biospecimens (3 samples)
- Sample 0DSPLQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSPLV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSPM2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
